TCGA case TCGA-55-8619 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Bronchus and lung; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/772324a5-5513-454d-ad6b-605798f69b73

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 72 years; Vital status: Alive.

Diagnoses (3)
1. Mucinous adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8480/3; ICD-10 code: C34.30; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 72.9 years (26,616 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Upper limb, NOS; Laterality: Left; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Mucinous adenocarcinoma: ICD-O-3 morphology code: 8480/3; Tissue or organ of origin: Lung, NOS; Laterality: Right; Classification of tumor: Synchronous primary; Age at diagnosis: 73.0 years (26,664 days); Days to diagnosis: 48 days; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 48 days; Treatment anatomic sites: Lung.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 49 days; Disease response: Tumor Free.
- Days to follow up: 416 days (1.1 years); Disease response: Tumor Free.
- Karnofsky performance status: 90; Timepoint: Preoperative.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-55-8619-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.8; Shortest dimension: 0.6.
  Slide TCGA-55-8619-01A-01-TS1: Section location: Top; Percent tumor cells: 72; Percent tumor nuclei: 60; Percent normal cells: 8; Percent necrosis: 5; Percent stromal cells: 15.
- Sample TCGA-55-8619-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-55-8619-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-55-8619-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.6; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Mucinous (Colloid) Carcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 1; Anatomic organ subdivision: R-Lower; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Arm; Other malignancy histological type: melanoma.
- Other malignancy form 1, Surgery: Other malignancy surgery type: excision.
- Other malignancy form 2: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Lung; Other malignancy histological type: Lung Mucinous Adenocarcinoma.
- Other malignancy form 2, Surgery: Other malignancy surgery type: lung pneumonectomy.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy melanoma of the L arm. No systemic chemotherapy or radiation. Patient with synchronous mucinous adenocarcinoma R lung.
- Synchronous malignancy: Prior malignancy melanoma of the L arm. No systemic chemotherapy or radiation. Patient with synchronous mucinous adenocarcinoma R lung.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 416 days; disease-specific survival: no event (censored), 416 days; disease-free interval: no event (censored), 416 days; progression-free interval: no event (censored), 416 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-55-8619-01A-11D-2389-01): tumor purity 0.24, ploidy 2.1, whole-genome doublings 0.
